Somatic mutation profile of tumor specimen ALCH-B2SK-TTP1-A (aliquot ALCH-B2SK-TTP1-A-1-0-D-A77K-36) from ALCHEMIST case ALCH-B2SK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 67.8 years (24,774 days).
Specimen ALCH-B2SK-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b6fae33-2e53-4441-9c70-e13d2b26c330.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2SK-NB1-A (Blood Derived Normal), aliquot ALCH-B2SK-NB1-A-1-0-D-A77K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90b6084b-8ea8-46e0-8416-16064ab1ebf4

The open-access MAF lists 675 somatic variants for this specimen: 464 protein-altering or splice-affecting, 132 silent, 79 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 386, Silent 132, Nonsense Mutation 36, Intron 32, Frame Shift Del 17, Splice Site 14, RNA 12, 5'Flank 12, 5'UTR 10, 3'UTR 9, 3'Flank 4, Translation Start Site 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RPE65 | c.1067dup p.N356Kfs*9 | Frame Shift Ins (INS) | VAF 73/374 reads (20%) | catalogued as rs281865520; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- TP53 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 79/219 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs762846821, CM951223, COSV52667239, COSV52783646, COSV53625267; called by muse, mutect2, varscan2
- ACTRT1 | c.528C>A p.H176Q | Missense Mutation (SNP) | VAF 46/321 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV100947550, COSV100947755; called by muse, mutect2, varscan2
- ADGRE1 | c.784C>A p.Q262K | Missense Mutation (SNP) | VAF 61/244 reads (25%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs1205502156; called by muse, mutect2, varscan2
- AKAP9 | c.10428A>T p.E3476D (on ENST00000359028; = p.E3452D on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/850 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.378); catalogued as COSV62350554; called by muse, mutect2
- ALK | c.1796del p.P599Lfs*66 | Frame Shift Del (DEL) | VAF 109/424 reads (26%) | catalogued as COSV66577265; called by mutect2, pindel, varscan2
- ALPL | c.1039C>G p.Q347E | Missense Mutation (SNP) | VAF 62/255 reads (24%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.71); catalogued as COSV66376506; called by muse, mutect2, varscan2
- AMDHD1 | c.1228C>G p.H410D | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760018743, COSV99701683; called by muse, mutect2
- ANKS1B | c.1595T>C p.I532T | Missense Mutation (SNP) | VAF 40/431 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as rs746993204, COSV61375509; called by muse, mutect2
- ARHGAP4 | c.1352G>T p.R451L | Missense Mutation (SNP) | VAF 57/377 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100603738; called by muse, mutect2, varscan2
- ARHGAP4 | c.562G>T p.A188S | Missense Mutation (SNP) | VAF 68/379 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV100604069; called by muse, mutect2, varscan2
- ATG2A | c.3034G>T p.A1012S | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs765221636; called by muse, mutect2, varscan2
- ATP2A3 | c.670G>A p.V224M | Missense Mutation (SNP) | VAF 75/217 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs370937213, COSV99989357; called by muse, mutect2, varscan2
- ATP7A | c.944G>T p.R315M | Missense Mutation (SNP) | VAF 57/372 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as COSV58452379; called by muse, mutect2, varscan2
- BRCC3 | c.943C>A p.L315I | Missense Mutation (SNP) | VAF 55/240 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.931); catalogued as COSV57462624, COSV57463109, COSV57463187; called by muse, mutect2, varscan2
- C1orf94 | c.175C>A p.Q59K | Missense Mutation (SNP) | VAF 80/599 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.445); catalogued as rs201119842; called by muse, mutect2, varscan2
- CACNA1I | c.532C>A p.R178S | Missense Mutation (SNP) | VAF 49/319 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60811663; called by muse, mutect2, varscan2
- CATSPER1 | c.1049C>A p.P350H | Missense Mutation (SNP) | VAF 54/365 reads (15%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.652); catalogued as COSV100376119; called by muse, mutect2, varscan2
- CCNE1 | c.1209G>T p.Q403H | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.365); catalogued as COSV52904305; called by muse, mutect2, varscan2
- CCSER1 | c.838A>G p.M280V | Missense Mutation (SNP) | VAF 13/253 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1402800347; called by muse, mutect2
- CCT3 | c.162G>T p.M54I | Missense Mutation (SNP) | VAF 106/480 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.113); catalogued as COSV99827512; called by muse, mutect2, varscan2
- CD163L1 | c.3979G>T p.A1327S | Missense Mutation (SNP) | VAF 121/462 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.516); catalogued as rs113454788; called by muse, mutect2, varscan2
- CD1B | c.839G>C p.R280P | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100939317, COSV63804179; called by muse, mutect2, varscan2
- CDH19 | c.978C>A p.H326Q | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV50956632; called by muse, mutect2
- CDH8 | c.1107G>T p.R369S | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV54851530; called by muse, mutect2
- CFAP99 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 58/523 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs1271847927; called by muse, mutect2, varscan2
- CHD4 | c.4846G>A p.E1616K (on ENST00000357008 / NM_001363606.2; = p.E1629K on NM_001273.5) | Missense Mutation (SNP) | VAF 122/301 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs760270237, COSV58906182; called by muse, mutect2, varscan2
- CNGB3 | c.1616G>T p.R539I | Missense Mutation (SNP) | VAF 131/440 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV60689117; called by muse, mutect2, varscan2
- COL11A2 | c.2326C>T p.R776C (on ENST00000341947 / NM_080680.3; = p.R669C on NM_080679.2) | Missense Mutation (SNP) | VAF 67/541 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs776701792, COSV59493332; called by muse, mutect2, varscan2
- COL11A2 | c.1720-1G>T p.X574_splice (on ENST00000341947 / NM_080680.3; = p.X467_splice on NM_080679.2) | Splice Site (SNP) | VAF 33/136 reads (24%) | catalogued as COSV59499551; called by muse, mutect2, varscan2
- COL6A6 | c.2288C>A p.T763N | Missense Mutation (SNP) | VAF 91/471 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs746683005; called by muse, mutect2, varscan2
- COL7A1 | c.3847C>T p.P1283S | Missense Mutation (SNP) | VAF 77/243 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.867); catalogued as rs921562127; called by muse, mutect2, varscan2
- CPED1 | c.2128A>G p.I710V | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.953); catalogued as rs759332316; called by muse, mutect2, varscan2
- CPS1 | c.1765G>T p.A589S | Missense Mutation (SNP) | VAF 66/640 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as CM063924; called by muse, mutect2, varscan2
- CRISP1 | c.452C>A p.S151Y | Missense Mutation (SNP) | VAF 161/492 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59995224; called by muse, mutect2, varscan2
- CSMD3 | c.140G>A p.W47* | Nonsense Mutation (SNP) | VAF 22/782 reads (3%) | catalogued as COSV99838135; called by muse, mutect2
- CTNNA3 | c.2452G>C p.V818L | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs747887589; called by muse, mutect2, varscan2
- DAPK1 | c.510T>A p.F170L | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.087); catalogued as rs776012850; called by muse, mutect2, varscan2
- DCC | c.2882G>A p.R961H | Missense Mutation (SNP) | VAF 181/916 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs776722332, COSV100501723; called by muse, mutect2, varscan2
- DDX24 | c.2299A>G p.M767V | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as rs770239129; called by muse, mutect2
- DKK1 | c.349C>A p.R117S | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.228); catalogued as COSV100906547; called by muse, mutect2, varscan2
- DLGAP1 | c.1070del p.G357Efs*52 | Frame Shift Del (DEL) | VAF 177/1673 reads (11%) | catalogued as COSV59823465; called by mutect2, pindel, varscan2
- DNAH5 | c.1564G>T p.E522* | Nonsense Mutation (SNP) | VAF 333/729 reads (46%) | catalogued as COSV54230614, COSV54246035; called by muse, mutect2, varscan2
- DRGX | c.356C>A p.S119Y | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs781448613; called by muse, mutect2, varscan2
- DUSP19 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 42/330 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745602817; called by muse, mutect2, varscan2
- EDNRB | c.823G>T p.V275L (on ENST00000377211 / NM_001201397.1; = p.V185L on NM_000115.5) | Missense Mutation (SNP) | VAF 99/374 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.399); catalogued as CM081580, COSV57520197, COSV57528867; called by muse, mutect2, varscan2
- ELOA2 | c.1824C>G p.Y608* | Nonsense Mutation (SNP) | VAF 81/314 reads (26%) | catalogued as rs267605191; called by muse, mutect2, varscan2
- ELP4 | c.869G>A p.R290H (on ENST00000350638; = p.R289H on NM_019040.5) | Missense Mutation (SNP) | VAF 42/347 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs1306122304, COSV63351761; called by muse, mutect2, varscan2
- EPHA3 | c.675G>T p.E225D | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); catalogued as COSV60706955; called by muse, mutect2, varscan2
- ESR1 | c.1301G>T p.R434L | Missense Mutation (SNP) | VAF 154/737 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV52791763; called by muse, mutect2, varscan2
- FAM163B | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as rs954229404; called by muse, mutect2, varscan2
- FAM170B | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 37/207 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs866574926, COSV61253270; called by muse, mutect2, varscan2
- FTCD | c.1478del p.G493Afs*10 | Frame Shift Del (DEL) | VAF 109/517 reads (21%) | catalogued as COSV52425977; called by mutect2, pindel, varscan2
- GLRA2 | c.203-1G>T p.X68_splice | Splice Site (SNP) | VAF 33/180 reads (18%) | catalogued as COSV99491797; called by muse, mutect2, varscan2
- GP2 | c.685T>A p.C229S (on ENST00000381362 / NM_001007240.3; = p.C226S on NM_001502.4) | Missense Mutation (SNP) | VAF 90/289 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56893701; called by muse, mutect2, varscan2
- GPR75 | c.112C>T p.H38Y | Missense Mutation (SNP) | VAF 150/457 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61830950; called by muse, mutect2, varscan2
- GREB1 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 84/243 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs972381553; called by muse, mutect2, varscan2
- HERC2 | c.10312G>C p.D3438H | Missense Mutation (SNP) | VAF 28/506 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); catalogued as COSV55335468; called by muse, mutect2
- IGSF3 | c.338G>T p.R113L | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); catalogued as COSV59585300; called by muse, mutect2, varscan2
- IL1RAP | c.1478G>T p.R493L | Missense Mutation (SNP) | VAF 184/551 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as rs148316157; called by muse, mutect2, varscan2
- INCENP | c.1282G>T p.G428W | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV99074430; called by muse, varscan2
- IQGAP2 | c.3950A>G p.N1317S | Missense Mutation (SNP) | VAF 69/302 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs745600734; called by muse, mutect2, varscan2
- IRS4 | c.2772G>T p.M924I | Missense Mutation (SNP) | VAF 136/695 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1166722507, COSV99058648; called by muse, mutect2, varscan2
- ITGA7 | c.1650G>T p.R550S (on ENST00000555728; = p.R506S on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 119/367 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs1370186788; called by muse, mutect2, varscan2
- ITGB1 | c.1314G>C p.K438N | Missense Mutation (SNP) | VAF 68/477 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV56484243; called by muse, mutect2, varscan2
- JAKMIP1 | c.1017G>T p.M339I | Missense Mutation (SNP) | VAF 61/311 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV51546940; called by muse, mutect2, varscan2
- KCNH7 | c.3380C>A p.S1127* | Nonsense Mutation (SNP) | VAF 34/244 reads (14%) | catalogued as COSV59795892; called by muse, mutect2, varscan2
- KIZ | c.1996G>A p.D666N | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as rs775652816, COSV55685300; called by muse, mutect2, varscan2
- KLHL30 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771702327; called by muse, mutect2, varscan2
- KLHL4 | c.1779C>A p.H593Q | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.915); catalogued as COSV64141611; called by muse, mutect2, varscan2
- KPRP | c.219G>T p.K73N | Missense Mutation (SNP) | VAF 80/291 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV100908722; called by muse, mutect2, varscan2
- KRT79 | c.1481G>T p.G494V | Missense Mutation (SNP) | VAF 160/386 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV57939032; called by muse, mutect2, varscan2
- KRTAP11-1 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 108/407 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.348); catalogued as COSV60095135; called by muse, mutect2, varscan2
- L1CAM | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 80/448 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.318); catalogued as rs369149142, COSV62827858; called by muse, mutect2, varscan2
- LEPR | c.762G>T p.K254N | Missense Mutation (SNP) | VAF 77/284 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as COSV100756590; called by muse, mutect2, varscan2
- LRIT2 | c.522G>T p.W174C | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs550705072, COSV64518099; called by muse, varscan2
- LRIT2 | c.521G>A p.W174* | Nonsense Mutation (SNP) | VAF 24/237 reads (10%) | catalogued as COSV64519195; called by muse, varscan2
- LRP2 | c.467C>A p.A156D | Missense Mutation (SNP) | VAF 75/452 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs769825555, COSV99787081; called by muse, mutect2, varscan2
- LRRC2 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 34/406 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.249); catalogued as rs750947485; called by muse, mutect2
- MAGEA11 | c.881C>G p.S294C | Missense Mutation (SNP) | VAF 62/371 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as COSV60758789; called by muse, mutect2, varscan2
- MAGEC1 | c.409T>C p.S137P | Missense Mutation (SNP) | VAF 38/361 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); catalogued as rs1391354613; called by muse, mutect2, varscan2
- MAGEL2 | c.638C>A p.P213Q | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious, low confidence (0); catalogued as COSV58568542; called by muse, mutect2, varscan2
- MAP2 | c.5230G>T p.D1744Y | Missense Mutation (SNP) | VAF 33/237 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99560851; called by muse, mutect2, varscan2
- MAP7D3 | c.2065G>T p.E689* | Nonsense Mutation (SNP) | VAF 35/285 reads (12%) | catalogued as COSV60171852; called by muse, mutect2, varscan2
- MCF2 | c.2433G>C p.Q811H | Missense Mutation (SNP) | VAF 27/255 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100644610; called by muse, mutect2, varscan2
- MEFV | c.2033G>T p.G678V | Missense Mutation (SNP) | VAF 87/372 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM012152; called by muse, mutect2, varscan2
- MEFV | c.1229G>T p.R410L | Missense Mutation (SNP) | VAF 68/219 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.041); catalogued as COSV54821238; called by muse, mutect2, varscan2
- METTL17 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 57/290 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775852895, COSV53870526; called by muse, mutect2, varscan2
- MTMR1 | c.1123C>A p.H375N | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as COSV100953129; called by muse, mutect2, varscan2
- MUC16 | c.27883A>G p.I9295V | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs1338852479; called by muse, mutect2, varscan2
- MYH11 | c.3667G>C p.D1223H | Missense Mutation (SNP) | VAF 68/221 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV55568909; called by muse, varscan2
- MYO7B | c.2971C>G p.R991G | Missense Mutation (SNP) | VAF 35/296 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV101268483; called by muse, mutect2, varscan2
- NACC2 | c.1489G>C p.A497P | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.112); catalogued as COSV53200899; called by mutect2, varscan2
- NDST4 | c.1988T>A p.L663Q | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs997231269; called by muse, mutect2, varscan2
- NEU4 | c.794G>T p.R265L (on ENST00000391969 / NM_001167602.3; = p.R277L on NM_080741.4) | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57989403; called by mutect2, varscan2
- NF1 | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 13/450 reads (3%) | catalogued as CM1311454, COSV62224610; called by muse, mutect2
- NOTCH1 | c.1904-1G>T p.X635_splice | Splice Site (SNP) | VAF 117/445 reads (26%) | catalogued as COSV53087809; called by muse, mutect2, varscan2
- NRG3 | c.1883C>A p.S628Y (on ENST00000404547 / NM_001370084.1; = p.S604Y on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 94/550 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV64564206; called by muse, mutect2, varscan2
- NRP1 | c.2222G>A p.R741H | Missense Mutation (SNP) | VAF 58/230 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs554872876, COSV55171299; called by muse, mutect2, varscan2
- OOEP | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 70/241 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV64859416; called by muse, mutect2, varscan2
- OR10AG1 | c.336C>A p.D112E | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1307734368, COSV56634903; called by muse, mutect2, varscan2
- OR13F1 | c.286G>T p.G96W | Missense Mutation (SNP) | VAF 78/279 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100594850; called by muse, mutect2, varscan2
- OR2B11 | c.799C>A p.P267T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.305); catalogued as COSV59511913; called by muse, mutect2, varscan2
- OR2T34 | c.641C>A p.T214N | Missense Mutation (SNP) | VAF 73/1154 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs771392433, COSV60900190; called by muse, mutect2
- OR3A1 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 52/207 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs368453639; called by muse, mutect2, varscan2
- OR4F6 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as rs776041979, COSV61026936; called by muse, mutect2, varscan2
- OR52A1 | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 52/493 reads (11%) | catalogued as COSV61092789; called by muse, mutect2, varscan2
- OR5P3 | c.676C>A p.L226M | Missense Mutation (SNP) | VAF 40/263 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.856); catalogued as COSV60430007; called by muse, mutect2, varscan2
- OR7C2 | c.524C>A p.P175Q | Missense Mutation (SNP) | VAF 67/352 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.409); catalogued as COSV50181428; called by muse, mutect2, varscan2
- P2RY8 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 6/131 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs751492615, COSV101184211; called by muse, mutect2
- PAPPA2 | c.1036C>A p.R346S | Missense Mutation (SNP) | VAF 71/608 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV62777763, COSV62780961; called by muse, mutect2, varscan2
- PARP1 | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 118/698 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.319); catalogued as rs1261041435; called by muse, mutect2, varscan2
- PCK1 | c.1506G>C p.Q502H | Missense Mutation (SNP) | VAF 126/585 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV60126665; called by muse, mutect2, varscan2
- PIEZO2 | c.4447C>T p.R1483C | Missense Mutation (SNP) | VAF 63/342 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs773994726; called by muse, mutect2, varscan2
- PIGM | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 137/700 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1280790306; called by muse, mutect2, varscan2
- PKD1L1 | c.5419C>T p.R1807* | Nonsense Mutation (SNP) | VAF 77/280 reads (28%) | catalogued as rs1464490636; called by muse, mutect2, varscan2
- PRR23A | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 64/411 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.709); catalogued as COSV101270269; called by muse, mutect2, varscan2
- PSD | c.621C>G p.F207L | Missense Mutation (SNP) | VAF 50/282 reads (18%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV50048482; called by muse, mutect2, varscan2
- PSG3 | c.769G>T p.V257F | Missense Mutation (SNP) | VAF 105/444 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.61); catalogued as rs766886576; called by muse, mutect2, varscan2
- RARA | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 62/238 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV99565541, COSV99565576; called by muse, mutect2, varscan2
- RELN | c.3987G>A p.M1329I | Missense Mutation (SNP) | VAF 255/875 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1562908501, COSV59040768; called by muse, mutect2, varscan2
- RIMS2 | c.2912G>T p.R971L (on ENST00000666250 / NM_001348490.2; = p.R779L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 87/399 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV51668611, COSV99169380; called by muse, mutect2, varscan2
- RIMS4 | c.377G>T p.R126L | Missense Mutation (SNP) | VAF 69/401 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); catalogued as COSV65720331; called by muse, mutect2, varscan2
- RSPO1 | c.675G>T p.R225S | Missense Mutation (SNP) | VAF 131/811 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV62975112; called by muse, mutect2, varscan2
- RYR2 | c.5480C>A p.T1827N | Missense Mutation (SNP) | VAF 233/804 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV63713324; called by muse, mutect2, varscan2
- S100A9 | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as rs1036690058; called by muse, mutect2
- SEMA3D | c.1645G>T p.D549Y | Missense Mutation (SNP) | VAF 85/375 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52398677, COSV52403601; called by muse, mutect2, varscan2
- SHANK3 | c.3775G>A p.A1259T | Missense Mutation (SNP) | VAF 56/306 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs747113407; called by muse, mutect2, varscan2
- SHC1 | c.440del p.G147Afs*79 (on ENST00000368445 / NM_183001.5; = p.G37Afs*79 on NM_003029.5) | Frame Shift Del (DEL) | VAF 94/426 reads (22%) | catalogued as rs1489363384; called by mutect2, pindel, varscan2
- SI | c.1061G>C p.G354A | Missense Mutation (SNP) | VAF 87/431 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52275021; called by muse, mutect2, varscan2
- SLC35F2 | c.677A>T p.Q226L | Missense Mutation (SNP) | VAF 25/254 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV56183645; called by muse, mutect2, varscan2
- SLC3A1 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 64/672 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142358712, CM983885, COSV99576814; called by muse, mutect2
- SLC49A3 | c.358G>T p.V120F | Missense Mutation (SNP) | VAF 116/439 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.036); catalogued as COSV59140681; called by muse, mutect2, varscan2
- SLC5A11 | c.1786G>T p.E596* | Nonsense Mutation (SNP) | VAF 40/188 reads (21%) | catalogued as COSV61740707; called by muse, varscan2
- SLCO1B1 | c.2047G>T p.A683S | Missense Mutation (SNP) | VAF 159/427 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs1304912903; called by muse, mutect2, varscan2
- SLCO1C1 | c.272-1G>A p.X91_splice | Splice Site (SNP) | VAF 110/240 reads (46%) | catalogued as COSV56869535; called by muse, mutect2, varscan2
- SLIT1 | c.2504G>A p.R835H | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1046200407, COSV56599634; called by muse, mutect2, varscan2
- SLX4IP | c.44T>C p.V15A | Missense Mutation (SNP) | VAF 62/297 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs780513282; called by muse, mutect2, varscan2
- SOX3 | c.697G>T p.G233C | Missense Mutation (SNP) | VAF 58/267 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100983705; called by muse, mutect2, varscan2
- SPATA31D1 | c.2989G>C p.G997R | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.194); catalogued as COSV61193711; called by muse, mutect2, varscan2
- SPIB | c.550A>T p.M184L | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs766612414; called by muse, mutect2
- TENT4B | c.1850C>T p.P617L (on ENST00000561678 / NM_001365323.2; = p.P602L on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/411 reads (28%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.216); catalogued as rs780697361; called by muse, mutect2, varscan2
- TEX15 | c.7615G>A p.D2539N (on ENST00000256246; = p.D2922N on NM_001350162.2) | Missense Mutation (SNP) | VAF 72/260 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as COSV56353718, COSV99821854; called by muse, mutect2, varscan2
- TGFB3 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 31/270 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.932); catalogued as rs1221353422; called by muse, mutect2, varscan2
- TKTL1 | c.928G>C p.V310L | Missense Mutation (SNP) | VAF 36/273 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as COSV54211970; called by muse, mutect2, varscan2
- TMEM215 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 52/205 reads (25%) | catalogued as COSV100713146; called by muse, mutect2, varscan2
- TNFAIP2 | c.1702-1G>A p.X568_splice | Splice Site (SNP) | VAF 10/41 reads (24%) | catalogued as COSV60695350; called by muse, mutect2, varscan2
- TNN | c.1777G>C p.G593R | Missense Mutation (SNP) | VAF 94/572 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1350092404; called by muse, mutect2, varscan2
- TNXB | c.5878G>C p.G1960R (on ENST00000647633; = p.G1713R on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/371 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100926582, COSV64483929; called by muse, mutect2, varscan2
- TRIML1 | c.759G>C p.R253S | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1206563992, COSV60194332, COSV60196016; called by muse, mutect2, varscan2
- TSGA10IP | c.449C>A p.S150Y | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV73245318; called by muse, mutect2, varscan2
- TTN | c.7657G>C p.E2553Q (on ENST00000591111; = p.E2507Q on NM_003319.4) | Missense Mutation (SNP) | VAF 47/300 reads (16%) | PolyPhen benign (0.369); catalogued as COSV60066571, COSV60407123; called by muse, mutect2, varscan2
- ULBP1 | c.8C>A p.A3E | Missense Mutation (SNP) | VAF 43/253 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0.058); catalogued as rs746363135, COSV57663653; called by muse, mutect2, varscan2
- UTP15 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 99/347 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1421002065; called by muse, mutect2, varscan2
- WEE2 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as rs752743808, COSV101285180, COSV66878222; called by muse, mutect2
- XPR1 | c.579G>C p.Q193H | Missense Mutation (SNP) | VAF 108/365 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.682); catalogued as COSV62554540; called by muse, mutect2, varscan2
- ZNF25 | c.1170del p.T391Lfs*97 | Frame Shift Del (DEL) | VAF 33/143 reads (23%) | catalogued as COSV56923926; called by mutect2, pindel, varscan2
- ZWINT | c.14A>T p.E5V | Missense Mutation (SNP) | VAF 42/240 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.165); catalogued as rs752579014, COSV100571493; called by muse, mutect2, varscan2
- ABCA8 | c.1417G>T p.E473* | Nonsense Mutation (SNP) | VAF 74/153 reads (48%) | called by muse, mutect2, varscan2
- ACSM2B | c.863T>A p.L288* | Nonsense Mutation (SNP) | VAF 29/103 reads (28%) | called by muse, mutect2, varscan2
- ACTN2 | c.2342G>T p.C781F | Missense Mutation (SNP) | VAF 292/970 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADAM29 | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.269); called by muse, mutect2
- AFF2 | c.3131C>G p.S1044C | Missense Mutation (SNP) | VAF 90/457 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- AGAP1 | c.1155+1G>T p.X385_splice | Splice Site (SNP) | VAF 22/170 reads (13%) | called by muse, mutect2, varscan2
- AICDA | c.39C>G p.Y13* | Nonsense Mutation (SNP) | VAF 118/494 reads (24%) | called by muse, mutect2, varscan2
- AL441992.2 | c.1190G>T p.S397I | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ALKBH7 | c.286G>C p.A96P | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALPI | c.1277C>A p.P426Q | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- ANO1 | c.1274A>T p.E425V | Missense Mutation (SNP) | VAF 45/288 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANO6 | c.1612G>T p.E538* | Nonsense Mutation (SNP) | VAF 56/184 reads (30%) | called by muse, mutect2, varscan2
- AR | c.2286G>T p.M762I | Missense Mutation (SNP) | VAF 68/352 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ARHGAP21 | c.3197+1del p.X1066_splice | Splice Site (DEL) | VAF 25/138 reads (18%) | called by mutect2, pindel, varscan2
- ARHGEF10 | c.443G>T p.G148V (on ENST00000398564; = p.G124V on NM_014629.4) | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ARHGEF9 | c.724C>A p.P242T | Missense Mutation (SNP) | VAF 72/365 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARMC3 | c.2435G>T p.G812V | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ASH2L | c.330G>T p.L110F | Missense Mutation (SNP) | VAF 128/1362 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- ATP2B3 | c.1608_1625del p.R537_K542del | In Frame Del (DEL) | VAF 42/241 reads (17%) | called by mutect2, pindel, varscan2
- ATP2B3 | c.2418C>A p.D806E | Missense Mutation (SNP) | VAF 79/389 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATP2B3 | c.2928C>A p.F976L | Missense Mutation (SNP) | VAF 107/593 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ATRX | c.2554G>T p.D852Y | Missense Mutation (SNP) | VAF 77/432 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- BBS7 | c.1872G>T p.Q624H | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- BCKDHB | c.875A>C p.K292T | Missense Mutation (SNP) | VAF 68/501 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- BCLAF1 | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- BCORL1 | c.1672G>C p.A558P | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- BCR | c.398G>T p.R133M | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- BIN2 | c.1349C>A p.A450D | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- BPIFA1 | c.550C>A p.P184T | Missense Mutation (SNP) | VAF 54/228 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- BRD9 | c.1010G>A p.S337N | Missense Mutation (SNP) | VAF 80/658 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- BRINP2 | c.1893G>T p.L631F | Missense Mutation (SNP) | VAF 31/249 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- BRINP2 | c.1894G>T p.G632W | Missense Mutation (SNP) | VAF 33/254 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BTN2A2 | c.1214G>T p.R405M | Missense Mutation (SNP) | VAF 82/338 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1orf35 | c.444C>G p.F148L | Missense Mutation (SNP) | VAF 78/382 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- C2orf73 | c.770G>T p.R257I | Missense Mutation (SNP) | VAF 36/306 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- CARD11 | c.2773A>T p.S925C | Missense Mutation (SNP) | VAF 67/340 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCDC150 | c.51_52del p.P18Nfs*9 | Frame Shift Del (DEL) | VAF 52/256 reads (20%) | called by pindel, varscan2
- CD207 | c.505A>T p.T169S | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CD47 | c.508G>T p.G170C | Missense Mutation (SNP) | VAF 51/405 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- CDC42BPG | c.3314G>T p.R1105L | Missense Mutation (SNP) | VAF 35/279 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDH18 | c.2063G>T p.R688L | Missense Mutation (SNP) | VAF 75/520 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CELF2 | c.1265G>T p.G422V (on ENST00000416382 / NM_001025077.3; = p.G435V on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP295 | c.2424A>T p.Q808H | Missense Mutation (SNP) | VAF 38/229 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CFAP47 | c.7928C>A p.P2643Q | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHSY1 | c.340C>G p.P114A | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- CKAP2 | c.1091C>G p.S364W (on ENST00000378037 / NM_001098525.2; = p.S363W on NM_018204.5) | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); called by muse, varscan2
- CLASP2 | c.1952-2A>T p.X651_splice | Splice Site (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- CNGA2 | c.111-2A>T p.X37_splice | Splice Site (SNP) | VAF 40/166 reads (24%) | called by muse, mutect2, varscan2
- CNGB1 | c.1344G>T p.E448D | Missense Mutation (SNP) | VAF 133/456 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- COL22A1 | c.3241-1G>T p.X1081_splice | Splice Site (SNP) | VAF 33/254 reads (13%) | called by muse, mutect2, varscan2
- CSMD2 | c.3372C>A p.C1124* | Nonsense Mutation (SNP) | VAF 90/267 reads (34%) | called by muse, mutect2, varscan2
- CST1 | c.211C>A p.L71I | Missense Mutation (SNP) | VAF 39/237 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- CYP1B1 | c.17G>T p.S6I | Missense Mutation (SNP) | VAF 69/575 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYP21A2 | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 110/635 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- DCAF12L2 | c.697T>A p.W233R | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DCUN1D2 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 62/248 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DMBT1 | c.5900G>T p.G1967V (on ENST00000338354 / NM_001377530.1; = p.G1210V on NM_004406.3) | Missense Mutation (SNP) | VAF 77/304 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DMD | c.10638G>T p.M3546I | Missense Mutation (SNP) | VAF 63/419 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH8 | c.8177C>A p.A2726E | Missense Mutation (SNP) | VAF 20/231 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.051); called by muse, mutect2
- DNAH8 | c.9642G>T p.W3214C | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DNAH8 | c.10362G>T p.Q3454H | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- DNAI1 | c.449C>A p.P150H | Missense Mutation (SNP) | VAF 152/442 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- DOCK10 | c.2444_2446del p.P815_N816delinsH | In Frame Del (DEL) | VAF 22/233 reads (9%) | called by mutect2, pindel, varscan2
- DPP10 | c.1046G>T p.C349F | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DRC7 | c.1399G>A p.D467N | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- DSCC1 | c.759T>A p.Y253* | Nonsense Mutation (SNP) | VAF 43/216 reads (20%) | called by muse, mutect2, varscan2
- ECEL1 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 65/248 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- EFCAB13 | c.1388C>A p.A463D | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); called by muse, mutect2
- EMD | c.440G>T p.C147F | Missense Mutation (SNP) | VAF 118/698 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ENAH | c.1198A>T p.K400* | Nonsense Mutation (SNP) | VAF 81/438 reads (18%) | called by muse, mutect2, varscan2
- EPC2 | c.1537C>T p.L513F | Missense Mutation (SNP) | VAF 39/280 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- EPS15 | c.1792-1G>T p.X598_splice | Splice Site (SNP) | VAF 176/335 reads (53%) | called by muse, mutect2, varscan2
- F8 | c.317C>T p.T106I | Missense Mutation (SNP) | VAF 81/485 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- FAM124B | c.1078G>T p.E360* | Nonsense Mutation (SNP) | VAF 80/628 reads (13%) | called by muse, mutect2, varscan2
- FAM124B | c.263C>G p.S88C | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- FAM83C | c.2110G>A p.G704S | Missense Mutation (SNP) | VAF 20/410 reads (5%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.026); called by muse, mutect2
- FAM83G | c.1286T>C p.I429T | Missense Mutation (SNP) | VAF 118/334 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- FBXL4 | c.1811T>C p.L604P | Missense Mutation (SNP) | VAF 44/225 reads (20%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- FCRL5 | c.2731G>T p.V911L | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- FGF13 | c.243G>T p.L81F | Missense Mutation (SNP) | VAF 50/351 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FGF5 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); called by muse, mutect2
- FGG | c.123C>A p.F41L | Missense Mutation (SNP) | VAF 104/450 reads (23%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FILIP1 | c.882G>T p.Q294H | Missense Mutation (SNP) | VAF 59/269 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- FKRP | c.368C>G p.T123S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.417); called by muse, mutect2
- FLVCR2 | c.846G>T p.R282S | Missense Mutation (SNP) | VAF 92/770 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- FRMD7 | c.1747C>A p.Q583K | Missense Mutation (SNP) | VAF 148/833 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- FXR2 | c.1652G>T p.R551L | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GIMAP6 | c.131T>A p.I44N | Missense Mutation (SNP) | VAF 26/259 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GINM1 | c.646_659del p.V216Ffs*7 | Frame Shift Del (DEL) | VAF 30/269 reads (11%) | called by mutect2, pindel, varscan2
- GLUD2 | c.417C>A p.H139Q | Missense Mutation (SNP) | VAF 123/767 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLYATL2 | c.698G>C p.R233T | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- GPNMB | c.250A>T p.S84C | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR107 | c.893T>C p.M298T | Missense Mutation (SNP) | VAF 55/226 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- GPR158 | c.3193C>A p.R1065S | Missense Mutation (SNP) | VAF 106/643 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR160 | c.755G>C p.W252S | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR3 | c.199G>T p.G67C | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- GPRIN2 | c.1106G>C p.G369A | Missense Mutation (SNP) | VAF 38/386 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.747); called by muse, mutect2
- GRID2 | c.2260C>A p.P754T | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GRM8 | c.1823A>T p.Y608F | Missense Mutation (SNP) | VAF 124/467 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- GRM8 | c.1822T>A p.Y608N | Missense Mutation (SNP) | VAF 122/465 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- GUCY1A2 | c.1306C>T p.R436* | Nonsense Mutation (SNP) | VAF 27/236 reads (11%) | called by muse, mutect2, varscan2
- GUF1 | c.626A>G p.Q209R | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, varscan2
- H3C2 | c.302T>A p.L101* | Nonsense Mutation (SNP) | VAF 100/487 reads (21%) | called by muse, mutect2, varscan2
- HAUS7 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 90/603 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HCFC1 | c.4282G>T p.G1428C | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HDAC6 | c.738-2A>T p.X246_splice | Splice Site (SNP) | VAF 116/423 reads (27%) | called by muse, mutect2, varscan2
- HIVEP2 | c.3044C>T p.S1015L | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- HM13 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 174/584 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- HMMR | c.579G>T p.M193I | Missense Mutation (SNP) | VAF 46/238 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- HYDIN | c.10477C>T p.L3493F | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.221); called by muse, varscan2
- ICE1 | c.3883A>T p.T1295S | Missense Mutation (SNP) | VAF 182/378 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.110T>G p.V37G | Missense Mutation (SNP) | VAF 146/503 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHV3-21 | c.172C>A p.Q58K | Missense Mutation (SNP) | VAF 124/923 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- IGHV4-28 | c.181C>A p.P61T | Missense Mutation (SNP) | VAF 163/636 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- IGLV3-32 | c.168G>T p.K56N | Missense Mutation (SNP) | VAF 57/486 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INSRR | c.2021G>T p.G674V | Missense Mutation (SNP) | VAF 46/343 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- INTS6L | c.842G>T p.G281V | Missense Mutation (SNP) | VAF 86/512 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- IPO8 | c.1169C>A p.P390H | Missense Mutation (SNP) | VAF 40/286 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- IRAK1 | c.1847G>C p.R616T | Missense Mutation (SNP) | VAF 77/440 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- ITGAD | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- ITGB8 | c.2213G>T p.C738F | Missense Mutation (SNP) | VAF 89/411 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- ITIH2 | c.2078C>A p.P693H | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2
- JAM3 | c.118A>T p.T40S | Missense Mutation (SNP) | VAF 60/419 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KCNA4 | c.557G>T p.R186L | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- KCP | c.2720G>T p.G907V (on ENST00000620378; = p.G967V on NM_001366122.1) | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- KIF18A | c.1778C>T p.S593L | Missense Mutation (SNP) | VAF 66/509 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIR3DX1 | n.956-2A>T | Splice Site (SNP) | VAF 38/189 reads (20%) | called by muse, varscan2
- KLHL1 | c.55dup p.W19Lfs*29 | Frame Shift Ins (INS) | VAF 8/50 reads (16%) | called by mutect2, pindel, varscan2
- KLHL14 | c.1023G>C p.L341F | Missense Mutation (SNP) | VAF 79/346 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KSR2 | c.2425A>C p.I809L | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- L1CAM | c.3773A>T p.*1258Lext*264 | Nonstop Mutation (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2
- LETM2 | c.327_360del p.K109Nfs*11 (on ENST00000379957 / NM_001286819.2; = p.K62Nfs*11 on NM_144652.3) | Frame Shift Del (DEL) | VAF 360/991 reads (36%) | called by mutect2, pindel
- LHX5 | c.1085A>G p.H362R | Missense Mutation (SNP) | VAF 93/236 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LPAR2 | c.356T>G p.V119G | Missense Mutation (SNP) | VAF 45/208 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- LRFN5 | c.855G>C p.E285D | Missense Mutation (SNP) | VAF 90/387 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- LRIT1 | c.1805G>T p.R602L | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- LRP1B | c.10546A>G p.T3516A | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRRK2 | c.3275A>G p.Y1092C | Missense Mutation (SNP) | VAF 14/466 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- LYPD8 | c.574A>G p.I192V | Missense Mutation (SNP) | VAF 120/629 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- MAGEA6 | c.644G>A p.C215Y | Missense Mutation (SNP) | VAF 95/638 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- MAP2 | c.3844G>T p.E1282* | Nonsense Mutation (SNP) | VAF 24/191 reads (13%) | called by muse, mutect2, varscan2
- MCOLN2 | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- MIB1 | c.2071A>C p.K691Q | Missense Mutation (SNP) | VAF 55/228 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- MRC2 | c.3965A>G p.E1322G | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MST1R | c.3076A>T p.I1026F | Missense Mutation (SNP) | VAF 86/261 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MTA3 | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 121/331 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- MTCL1 | c.2337G>T p.E779D (on ENST00000306329 / NM_001378206.1; = p.E419D on NM_015210.4) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.075); called by muse, mutect2
- MTF1 | c.871T>C p.C291R | Missense Mutation (SNP) | VAF 109/285 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- MTMR11 | c.760G>T p.G254C (on ENST00000439741 / NM_001145862.2; = p.G182C on NM_181873.3) | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- MUC12 | c.16369C>A p.L5457M (on ENST00000379442; = p.L5314M on NM_001164462.1) | Missense Mutation (SNP) | VAF 66/220 reads (30%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2, varscan2
- MUC19 | c.658A>T p.T220S | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- MYH2 | c.566C>A p.T189N | Missense Mutation (SNP) | VAF 210/763 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- MYH7 | c.2042C>A p.P681Q | Missense Mutation (SNP) | VAF 68/519 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO16 | c.2440G>T p.E814* | Nonsense Mutation (SNP) | VAF 48/202 reads (24%) | called by muse, varscan2
- MYOM3 | c.3454C>T p.Q1152* | Nonsense Mutation (SNP) | VAF 61/499 reads (12%) | called by muse, mutect2, varscan2
- MYT1L | c.1181G>T p.R394I | Missense Mutation (SNP) | VAF 161/456 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- NCAN | c.2661G>T p.M887I | Missense Mutation (SNP) | VAF 60/222 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NDUFA1 | c.102G>T p.K34N | Missense Mutation (SNP) | VAF 63/330 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NF1 | c.73del p.T25Qfs*19 | Frame Shift Del (DEL) | VAF 56/334 reads (17%) | called by mutect2, pindel, varscan2
- NLRP8 | c.682del p.A228Pfs*21 | Frame Shift Del (DEL) | VAF 85/457 reads (19%) | called by mutect2, pindel, varscan2
- NOXO1 | c.192del p.R65Dfs*77 (on ENST00000397280 / NM_172168.3; = p.R64Dfs*72 on NM_144603.4) | Frame Shift Del (DEL) | VAF 35/115 reads (30%) | called by mutect2, pindel*, varscan2
- NPIPA3 | c.725G>T p.R242M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.452); called by mutect2, varscan2
- NPY1R | c.213G>T p.M71I | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- NQO1 | c.576C>A p.S192R | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- NSUN4 | c.1078G>T p.V360F | Missense Mutation (SNP) | VAF 195/386 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NTSR1 | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 69/276 reads (25%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR14I1 | c.248C>A p.S83Y | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OR2AT4 | c.251C>A p.P84H | Missense Mutation (SNP) | VAF 48/383 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2S2 | c.499C>A p.L167M | Missense Mutation (SNP) | VAF 127/479 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR2T1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 42/277 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR2W3 | c.722G>C p.C241S | Missense Mutation (SNP) | VAF 94/385 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- OR4C13 | c.317G>T p.R106I | Missense Mutation (SNP) | VAF 30/245 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4X2 | c.467_473del p.F156Cfs*8 | Frame Shift Del (DEL) | VAF 54/420 reads (13%) | called by mutect2, pindel, varscan2
- OR5B12 | c.217T>A p.S73T | Missense Mutation (SNP) | VAF 30/244 reads (12%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OR5D13 | c.567del p.S190Pfs*21 | Frame Shift Del (DEL) | VAF 41/270 reads (15%) | called by mutect2, pindel, varscan2
- OR6B2 | c.113T>C p.V38A | Missense Mutation (SNP) | VAF 52/577 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.103); called by muse, mutect2
- OR9G1 | c.895G>C p.A299P | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- OSBPL8 | c.868A>T p.T290S | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTULINL | c.328C>G p.R110G | Missense Mutation (SNP) | VAF 226/493 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- OTX2 | c.737C>G p.S246* (on ENST00000408990 / NM_172337.3; = p.S254* on NM_021728.4) | Nonsense Mutation (SNP) | VAF 61/584 reads (10%) | called by muse, mutect2, varscan2
- PAK3 | c.1397T>C p.M466T (on ENST00000262836 / NM_001324328.2; = p.M451T on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/419 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAPPA2 | c.4537C>A p.L1513I | Missense Mutation (SNP) | VAF 102/474 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PAPPA2 | c.5021G>T p.G1674V | Missense Mutation (SNP) | VAF 78/380 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHGA8 | c.2168G>T p.R723L | Missense Mutation (SNP) | VAF 71/327 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- PDE11A | c.2423+1G>T p.X808_splice | Splice Site (SNP) | VAF 14/181 reads (8%) | called by muse, mutect2
- PDE4DIP | c.6892G>T p.E2298* | Nonsense Mutation (SNP) | VAF 42/205 reads (20%) | called by muse, mutect2, varscan2
- PGK1 | c.547C>G p.Q183E | Missense Mutation (SNP) | VAF 151/708 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- PHKA1 | c.1706G>T p.S569I | Missense Mutation (SNP) | VAF 80/648 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- PHKB | c.2125G>T p.G709* | Nonsense Mutation (SNP) | VAF 127/431 reads (29%) | called by muse, mutect2, varscan2
- PIM3 | c.934G>C p.D312H | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- PKD1L3 | c.2952G>T p.Q984H | Missense Mutation (SNP) | VAF 83/314 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PLG | c.145T>A p.C49S | Missense Mutation (SNP) | VAF 63/349 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PLXNA1 | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 64/268 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- PLXNA4 | c.3013G>T p.V1005F | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- PNPT1 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 37/337 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- POLR2I | c.145G>T p.D49Y | Missense Mutation (SNP) | VAF 74/422 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- PPP4R3C | c.1116G>A p.M372I | Missense Mutation (SNP) | VAF 38/282 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PREX2 | c.3839A>T p.E1280V | Missense Mutation (SNP) | VAF 127/687 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- PRKCG | c.1811G>T p.G604V | Missense Mutation (SNP) | VAF 151/556 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRRC2B | c.1526G>T p.R509L | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PRSS38 | c.457del p.L153Wfs*4 | Frame Shift Del (DEL) | VAF 84/619 reads (14%) | called by mutect2, pindel, varscan2
- PTH2R | c.200G>T p.W67L | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTPRZ1 | c.1879G>T p.A627S | Missense Mutation (SNP) | VAF 40/244 reads (16%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RAB25 | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- RAB40A | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 74/354 reads (21%) | called by muse, mutect2, varscan2
- RAD51B | c.84G>C p.Q28H | Missense Mutation (SNP) | VAF 58/201 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- RANGAP1 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 28/221 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RBM15B | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 30/116 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- RBMX2 | c.535G>C p.V179L | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2
- RCOR1 | c.1058A>T p.Q353L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- REG1A | c.104G>T p.S35I | Missense Mutation (SNP) | VAF 84/578 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- RET | c.952C>A p.L318M | Missense Mutation (SNP) | VAF 51/419 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- REV1 | c.1931A>C p.Q644P | Missense Mutation (SNP) | VAF 39/264 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- RFPL3 | c.249G>T p.M83I (on ENST00000249007 / NM_001098535.1; = p.M54I on NM_006604.2) | Missense Mutation (SNP) | VAF 105/477 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIN2 | c.642_650del p.F214_D216del (on ENST00000255006 / NM_001242581.1; = p.F165_D167del on NM_018993.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 30/332 reads (9%) | called by mutect2, pindel
- RORB | c.749G>T p.W250L (on ENST00000396204 / NM_001365023.1; = p.W239L on NM_006914.4) | Missense Mutation (SNP) | VAF 37/229 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- RTL1 | c.322C>G p.Q108E | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- RTL4 | c.307del p.L103Yfs*5 | Frame Shift Del (DEL) | VAF 38/261 reads (15%) | called by mutect2, pindel, varscan2
- RYR1 | c.798C>A p.I266= | Splice Region (SNP) | VAF 27/104 reads (26%) | called by muse, mutect2, varscan2
- RYR1 | c.5980C>A p.R1994S | Missense Mutation (SNP) | VAF 107/485 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- RYR2 | c.170A>T p.N57I | Missense Mutation (SNP) | VAF 211/677 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- RYR2 | c.11864A>T p.Q3955L | Missense Mutation (SNP) | VAF 52/406 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- RYR2 | c.13391A>G p.Q4464R | Missense Mutation (SNP) | VAF 111/399 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCG5 | c.625A>T p.K209* (on ENST00000300175 / NM_001144757.2; = p.K208* on NM_003020.4) | Nonsense Mutation (SNP) | VAF 85/277 reads (31%) | called by muse, mutect2, varscan2
- SCN2A | c.5197C>A p.P1733T | Missense Mutation (SNP) | VAF 59/436 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SDK2 | c.2526G>T p.M842I | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SEMA6D | c.733A>G p.N245D | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- SENP7 | c.358A>T p.N120Y | Missense Mutation (SNP) | VAF 608/1137 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- SEZ6L | c.1366G>T p.V456L | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- SH3BP4 | c.1536G>T p.Q512H | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SHB | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 10/298 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.341); called by muse, mutect2
- SIGLEC7 | c.125T>C p.V42A | Missense Mutation (SNP) | VAF 119/520 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SIM1 | c.1049C>G p.S350C | Missense Mutation (SNP) | VAF 64/510 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SIN3B | c.504T>A p.Y168* | Nonsense Mutation (SNP) | VAF 94/360 reads (26%) | called by muse, mutect2, varscan2
- SKAP2 | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 24/299 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2
- SLAMF7 | c.478G>T p.V160L | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC17A1 | c.137T>A p.V46D | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- SLC17A2 | c.1250G>T p.G417V (on ENST00000265425; = p.G368C on NM_005835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/291 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- SLC1A5 | c.791A>T p.E264V | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- SLC25A48 | c.431G>T p.G144V (on ENST00000650267; = p.G90V on NM_001349335.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- SLC34A3 | c.331G>C p.D111H | Missense Mutation (SNP) | VAF 124/474 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- SLC5A6 | c.831G>T p.Q277H | Missense Mutation (SNP) | VAF 66/446 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC8A3 | c.786C>A p.H262Q | Missense Mutation (SNP) | VAF 62/515 reads (12%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SLITRK2 | c.935C>T p.T312I | Missense Mutation (SNP) | VAF 49/300 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLITRK2 | c.1148C>A p.T383K | Missense Mutation (SNP) | VAF 59/427 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPATA31A6 | c.3268C>A p.Q1090K | Missense Mutation (SNP) | VAF 245/593 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- SPATA31D1 | c.3886C>A p.P1296T | Missense Mutation (SNP) | VAF 62/278 reads (22%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- SPPL2C | c.478G>T p.D160Y | Missense Mutation (SNP) | VAF 84/310 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SPTA1 | c.4565C>A p.T1522K | Missense Mutation (SNP) | VAF 122/618 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- SPTB | c.3985C>G p.L1329V | Missense Mutation (SNP) | VAF 35/426 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- SPTBN5 | c.1150C>A p.P384T | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- SRPK3 | c.1126G>T p.G376W | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- STYXL2 | c.2465C>A p.P822H | Missense Mutation (SNP) | VAF 46/249 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SV2C | c.1078C>A p.L360M | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SVEP1 | c.2740A>G p.I914V | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SYNE1 | c.16126A>T p.K5376* (on ENST00000367255 / NM_182961.4; = p.K5305* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 51/260 reads (20%) | called by muse, mutect2, varscan2
- SYNGR1 | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 69/595 reads (12%) | called by muse, mutect2, varscan2
- SYTL4 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TACC2 | c.7811A>T p.E2604V (on ENST00000334433; = p.E682V on NM_006997.4) | Missense Mutation (SNP) | VAF 32/304 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- TARBP1 | c.3039G>T p.Q1013H | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); called by muse, mutect2
- TARM1 | c.774C>A p.F258L (on ENST00000616041 / NM_001330650.1; = p.F250L on NM_001135686.3) | Missense Mutation (SNP) | VAF 71/339 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, varscan2
- TBC1D32 | c.3594A>T p.K1198N | Missense Mutation (SNP) | VAF 40/232 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- TCP11X2 | c.735G>T p.W245C | Missense Mutation (SNP) | VAF 88/761 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- TENM1 | c.7922A>T p.E2641V | Missense Mutation (SNP) | VAF 74/256 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- TEX13C | c.1230G>T p.M410I | Missense Mutation (SNP) | VAF 122/534 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TEX13C | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 140/752 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- TEX22 | c.279G>T p.R93S | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2
- TFB1M | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 147/691 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- TGM4 | c.616A>T p.R206W | Missense Mutation (SNP) | VAF 67/238 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- THBS2 | c.1263G>T p.Q421H | Missense Mutation (SNP) | VAF 93/417 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- THOC2 | c.714G>C p.M238I | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- TIAM2 | c.2926G>T p.D976Y | Missense Mutation (SNP) | VAF 108/528 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- TMEM132B | c.2455G>T p.E819* | Nonsense Mutation (SNP) | VAF 95/276 reads (34%) | called by muse, mutect2, varscan2
- TMEM132D | c.1345G>T p.A449S | Missense Mutation (SNP) | VAF 93/296 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.309); called by muse, varscan2
- TMEM151B | c.200T>C p.L67P | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TMEM225B | c.189del p.W63* | Frame Shift Del (DEL) | VAF 32/255 reads (13%) | called by mutect2, pindel, varscan2
- TMEM241 | c.329G>T p.C110F | Missense Mutation (SNP) | VAF 52/325 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMUB1 | c.37G>T p.V13F | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.109); called by muse, varscan2
- TNNT1 | c.837A>T p.*279Cext*21 | Nonstop Mutation (SNP) | VAF 99/445 reads (22%) | called by muse, mutect2, varscan2
- TNXB | c.2746G>A p.V916I | Missense Mutation (SNP) | VAF 55/224 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- TNXB | c.1664G>C p.S555T | Missense Mutation (SNP) | VAF 98/510 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- TOMM70 | c.1667T>C p.V556A | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- TRAV27 | c.116T>A p.V39E | Missense Mutation (SNP) | VAF 92/335 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- TRIM69 | c.323T>A p.L108* | Nonsense Mutation (SNP) | VAF 203/526 reads (39%) | called by muse, mutect2, varscan2
- TRIP12 | c.698G>C p.R233P | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- TRPC1 | c.1423G>T p.V475F (on ENST00000476941 / NM_001251845.2; = p.V441F on NM_003304.4) | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); called by muse, mutect2
- TRPC5 | c.1924G>T p.A642S | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPC5 | c.934G>T p.A312S | Missense Mutation (SNP) | VAF 59/247 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TTI1 | c.2433G>T p.Q811H | Missense Mutation (SNP) | VAF 134/603 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TUT7 | c.3740A>G p.E1247G | Missense Mutation (SNP) | VAF 48/218 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- USH2A | c.5692del p.V1898Lfs*34 | Frame Shift Del (DEL) | VAF 90/509 reads (18%) | called by mutect2, pindel, varscan2
- WASF1 | c.1349A>T p.H450L | Missense Mutation (SNP) | VAF 94/474 reads (20%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- WDFY4 | c.4817C>A p.P1606H | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- WDR33 | c.3268G>C p.D1090H | Missense Mutation (SNP) | VAF 40/288 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- ZFC3H1 | c.750G>C p.L250F | Missense Mutation (SNP) | VAF 98/313 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZGRF1 | c.2757A>T p.Q919H | Missense Mutation (SNP) | VAF 63/326 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ZNF138 | c.770G>T p.G257V (on ENST00000307355 / NM_001367572.1; = p.G231V on NM_006524.4) | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZNF146 | c.669G>C p.Q223H | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF257 | c.205G>C p.E69Q | Missense Mutation (SNP) | VAF 32/530 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.133); called by muse, mutect2
- ZNF311 | c.893C>G p.T298R | Missense Mutation (SNP) | VAF 104/495 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ZNF444 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 21/79 reads (27%) | called by muse, mutect2, varscan2
- ZNF460 | c.48G>T p.E16D | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ZNF665 | c.1112G>T p.G371V (on ENST00000600412; = p.G436V on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ZNF674 | c.773C>G p.A258G | Missense Mutation (SNP) | VAF 62/411 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF737 | c.814C>T p.L272F | Missense Mutation (SNP) | VAF 128/591 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- ZP1 | c.406C>A p.P136T | Missense Mutation (SNP) | VAF 15/171 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ABCA2 | c.1191G>T p.A397= (on ENST00000614293; = p.A367= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/86 reads (33%) | called by muse, mutect2, varscan2
- ACTRT2 | c.940C>A p.R314= | Silent (SNP) | VAF 70/275 reads (25%) | catalogued as COSV65760383, COSV65760418; called by muse, mutect2, varscan2
- ADGRB1 | c.2688C>T p.S896= | Silent (SNP) | VAF 36/114 reads (32%) | called by muse, mutect2, varscan2
- ADGRE3 | c.1161C>G p.T387= | Silent (SNP) | VAF 164/621 reads (26%) | called by muse, mutect2, varscan2
- ADGRG7 | c.1869G>A p.P623= | Silent (SNP) | VAF 16/232 reads (7%) | catalogued as rs779783414, COSV56295824, COSV99841520; called by muse, mutect2
- AGO1 | c.573G>T p.G191= | Silent (SNP) | VAF 131/305 reads (43%) | called by muse, mutect2, varscan2
- AGTR1 | c.516T>A p.I172= | Silent (SNP) | VAF 14/128 reads (11%) | called by muse, mutect2
- AHNAK | c.8790G>C p.V2930= | Silent (SNP) | VAF 57/388 reads (15%) | called by muse, mutect2, varscan2
- ARHGAP4 | c.1353G>T p.R451= | Silent (SNP) | VAF 58/383 reads (15%) | called by muse, mutect2, varscan2
- ARHGEF11 | c.642G>A p.L214= | Silent (SNP) | VAF 73/490 reads (15%) | called by muse, mutect2, varscan2
- ASPDH | c.408A>G p.R136= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as rs752142353; called by muse, mutect2, varscan2
- ATAD2B | c.3555G>A p.E1185= | Silent (SNP) | VAF 100/242 reads (41%) | catalogued as rs753350309; called by muse, mutect2, varscan2
- ATP1A2 | c.2226A>G p.A742= | Silent (SNP) | VAF 75/409 reads (18%) | called by muse, mutect2, varscan2
- ATP1A3 | c.504G>T p.V168= (on ENST00000545399 / NM_001256214.2; = p.V155= on NM_152296.5) | Silent (SNP) | VAF 87/512 reads (17%) | called by muse, mutect2, varscan2
- AWAT1 | c.405C>A p.A135= | Silent (SNP) | VAF 97/543 reads (18%) | called by muse, mutect2, varscan2
- BPIFA1 | c.552T>C p.P184= | Silent (SNP) | VAF 54/222 reads (24%) | catalogued as rs766293025; called by muse, mutect2
- BRSK1 | c.342G>T p.S114= | Silent (SNP) | VAF 58/216 reads (27%) | catalogued as rs142000353; called by muse, mutect2, varscan2
- C4orf54 | c.30G>T p.R10= | Silent (SNP) | VAF 28/91 reads (31%) | called by muse, mutect2, varscan2
- CACNA1S | c.4407C>G p.A1469= | Silent (SNP) | VAF 158/727 reads (22%) | called by muse, mutect2, varscan2
- CCDC115 | c.498G>T p.R166= | Silent (SNP) | VAF 29/236 reads (12%) | called by muse, mutect2, varscan2
- CCDC14 | c.2409A>G p.K803= (on ENST00000488653; = p.K755= on NM_022757.5) | Silent (SNP) | VAF 28/350 reads (8%) | called by muse, mutect2
- CCDC88C | c.3549C>T p.A1183= | Silent (SNP) | VAF 45/240 reads (19%) | catalogued as rs369163210; called by muse, mutect2, varscan2
- CLEC1B | c.303C>A p.P101= | Silent (SNP) | VAF 74/287 reads (26%) | called by muse, mutect2, varscan2
- CSMD1 | c.1386A>G p.R462= (on ENST00000520002; = p.R461= on NM_033225.6) | Silent (SNP) | VAF 28/331 reads (8%) | called by muse, mutect2
- CTAGE6 | c.954G>A p.L318= | Silent (SNP) | VAF 124/1400 reads (9%) | catalogued as rs1267091406; called by muse, varscan2
- CYP51A1 | c.45G>T p.A15= | Silent (SNP) | VAF 285/443 reads (64%) | called by muse, mutect2, varscan2
- DCAF12L1 | c.489T>A p.L163= | Silent (SNP) | VAF 69/429 reads (16%) | called by muse, mutect2, varscan2
- DCC | c.612G>T p.P204= | Silent (SNP) | VAF 96/402 reads (24%) | called by muse, mutect2, varscan2
- DENND2A | c.186T>A p.P62= | Silent (SNP) | VAF 43/133 reads (32%) | called by muse, mutect2, varscan2
- DOK6 | c.531G>C p.V177= | Silent (SNP) | VAF 84/353 reads (24%) | catalogued as COSV101234824; called by muse, mutect2, varscan2
- DPRX | c.399G>T p.L133= | Silent (SNP) | VAF 44/212 reads (21%) | called by muse, mutect2, varscan2
- EFHB | c.1443C>A p.S481= | Silent (SNP) | VAF 32/145 reads (22%) | catalogued as COSV55552012; called by muse, mutect2, varscan2
- F5 | c.3675C>A p.A1225= | Silent (SNP) | VAF 163/871 reads (19%) | called by muse, mutect2, varscan2
- FAM155A | c.150C>G p.V50= | Silent (SNP) | VAF 74/286 reads (26%) | catalogued as COSV65562916; called by muse, varscan2
- FCRL6 | c.24G>A p.L8= | Silent (SNP) | VAF 38/273 reads (14%) | called by muse, mutect2
- FGF4 | c.327G>T p.A109= | Silent (SNP) | VAF 37/232 reads (16%) | called by muse, mutect2, varscan2
- FLNA | c.6894G>T p.V2298= (on ENST00000369850 / NM_001110556.2; = p.V2290= on NM_001456.3) | Silent (SNP) | VAF 100/622 reads (16%) | called by muse, mutect2, varscan2
- FMO3 | c.1476G>T p.R492= | Silent (SNP) | VAF 42/260 reads (16%) | called by muse, mutect2, varscan2
- FOXF2 | c.48C>T p.C16= | Silent (SNP) | VAF 14/69 reads (20%) | called by muse, varscan2
- FRMPD3 | c.4317C>A p.A1439= | Silent (SNP) | VAF 22/95 reads (23%) | called by muse, mutect2, varscan2
- GAS7 | c.1416G>A p.V472= (on ENST00000432992 / NM_201433.2; = p.V332= on NM_003644.3) | Silent (SNP) | VAF 77/219 reads (35%) | called by muse, mutect2, varscan2
- GFI1 | c.930G>C p.R310= | Silent (SNP) | VAF 99/394 reads (25%) | called by muse, mutect2, varscan2
- GGT2 | c.534G>A p.L178= | Silent (SNP) | VAF 50/749 reads (7%) | called by muse, mutect2
- GRIA3 | c.2091T>A p.A697= | Silent (SNP) | VAF 88/438 reads (20%) | called by muse, mutect2, varscan2
- GRM5 | c.2070C>A p.A690= | Silent (SNP) | VAF 61/329 reads (19%) | catalogued as COSV59625728; called by muse, mutect2, varscan2
- HAUS5 | c.1533C>T p.L511= | Silent (SNP) | VAF 45/184 reads (24%) | catalogued as rs771826162; called by muse, mutect2, varscan2
- HOMER3 | c.87A>G p.P29= | Silent (SNP) | VAF 72/366 reads (20%) | called by muse, mutect2, varscan2
- HS1BP3 | c.720G>T p.G240= | Silent (SNP) | VAF 48/149 reads (32%) | catalogued as COSV100398132; called by muse, mutect2, varscan2
- IRAK1BP1 | c.153C>T p.R51= | Silent (SNP) | VAF 122/605 reads (20%) | called by muse, mutect2, varscan2
- IRX2 | c.846C>T p.P282= | Silent (SNP) | VAF 261/503 reads (52%) | catalogued as COSV57410725; called by muse, mutect2, varscan2
- KCNH7 | c.1854T>A p.L618= | Silent (SNP) | VAF 28/275 reads (10%) | called by muse, mutect2, varscan2
- KIAA1210 | c.3138G>A p.V1046= | Silent (SNP) | VAF 94/467 reads (20%) | called by muse, mutect2, varscan2
- KIF21B | c.933G>T p.G311= | Silent (SNP) | VAF 70/337 reads (21%) | catalogued as rs778081050; called by muse, mutect2, varscan2
- KIF4A | c.210G>A p.A70= | Silent (SNP) | VAF 54/237 reads (23%) | catalogued as rs755499983; called by muse, mutect2, varscan2
- LAMA2 | c.8040T>C p.F2680= | Silent (SNP) | VAF 114/543 reads (21%) | called by muse, mutect2, varscan2
- LHX5 | c.267T>C p.C89= | Silent (SNP) | VAF 97/281 reads (35%) | called by muse, mutect2, varscan2
- LILRB1 | c.610C>T p.L204= (on ENST00000427581; = p.L168= on NM_006669.6) | Silent (SNP) | VAF 23/621 reads (4%) | catalogued as rs781081505; called by muse, mutect2
- LINGO2 | c.816G>T p.L272= | Silent (SNP) | VAF 67/278 reads (24%) | catalogued as rs1220736151, COSV100430271; called by muse, mutect2, varscan2
- LRFN5 | c.567G>T p.G189= | Silent (SNP) | VAF 26/195 reads (13%) | catalogued as COSV53261249; called by muse, mutect2, varscan2
- LRIT1 | c.1764C>A p.S588= | Silent (SNP) | VAF 75/363 reads (21%) | called by muse, varscan2
- MAP7D2 | c.1080A>G p.L360= | Silent (SNP) | VAF 56/285 reads (20%) | called by muse, mutect2, varscan2
- MOCS1 | c.174C>T p.S58= | Silent (SNP) | VAF 51/388 reads (13%) | catalogued as rs776528157, COSV57937105; called by muse, mutect2, varscan2
- MROH5 | c.2931C>G p.T977= | Silent (SNP) | VAF 40/191 reads (21%) | called by muse, mutect2, varscan2
- MYO7B | c.2187C>T p.D729= | Silent (SNP) | VAF 25/196 reads (13%) | catalogued as COSV67347743; called by muse, mutect2, varscan2
- NAP1L3 | c.75G>T p.S25= | Silent (SNP) | VAF 44/210 reads (21%) | called by muse, varscan2
- NBAS | c.1380G>A p.E460= | Silent (SNP) | VAF 112/304 reads (37%) | called by muse, mutect2, varscan2
- NBPF12 | c.258G>T p.L86= | Silent (SNP) | VAF 169/727 reads (23%) | catalogued as COSV58767588, COSV58777785; called by muse, mutect2, varscan2
- NFATC2 | c.594C>T p.P198= | Silent (SNP) | VAF 77/284 reads (27%) | catalogued as rs201971596; called by muse, mutect2, varscan2
- NPHS2 | c.471C>A p.P157= | Silent (SNP) | VAF 121/666 reads (18%) | called by mutect2, varscan2
- NPTX2 | c.351G>A p.P117= | Silent (SNP) | VAF 33/332 reads (10%) | called by muse, mutect2, varscan2
- OR2F2 | c.237C>G p.P79= | Silent (SNP) | VAF 31/219 reads (14%) | called by muse, mutect2, varscan2
- OR2L13 | c.579C>G p.V193= | Silent (SNP) | VAF 96/435 reads (22%) | catalogued as COSV100813898, COSV63552866, COSV63563729; called by muse, mutect2, varscan2
- OR2T11 | c.876G>A p.K292= | Silent (SNP) | VAF 86/839 reads (10%) | called by muse, mutect2, varscan2
- OR2T35 | c.591C>A p.T197= | Silent (SNP) | VAF 134/1668 reads (8%) | called by muse, mutect2
- OR52I2 | c.204C>A p.A68= | Silent (SNP) | VAF 58/755 reads (8%) | called by muse, mutect2
- OR5T3 | c.456C>A p.V152= | Silent (SNP) | VAF 32/219 reads (15%) | called by muse, mutect2, varscan2
- OR6K6 | c.852C>A p.V284= (on ENST00000368144; = p.V260= on NM_001005184.1) | Silent (SNP) | VAF 60/278 reads (22%) | called by muse, mutect2, varscan2
- PCDHA11 | c.1449G>A p.A483= | Silent (SNP) | VAF 182/639 reads (28%) | called by muse, mutect2, varscan2
- PIEZO2 | c.7848C>T p.I2616= | Silent (SNP) | VAF 108/339 reads (32%) | called by muse, mutect2, varscan2
- PIGZ | c.1566A>G p.V522= | Silent (SNP) | VAF 83/249 reads (33%) | called by muse, mutect2, varscan2
- PIK3R5 | c.1254G>T p.G418= | Silent (SNP) | VAF 42/139 reads (30%) | called by muse, mutect2, varscan2
- PLCG2 | c.1158G>T p.V386= | Silent (SNP) | VAF 69/295 reads (23%) | catalogued as rs774804571, COSV63872764; called by muse, mutect2, varscan2
- PLEC | c.2199G>A p.R733= (on ENST00000322810 / NM_201380.4; = p.R623= on NM_000445.5) | Silent (SNP) | VAF 158/539 reads (29%) | called by muse, mutect2, varscan2
- PLEKHG2 | c.4014G>T p.T1338= | Silent (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- PLPPR4 | c.516C>T p.L172= | Silent (SNP) | VAF 18/89 reads (20%) | called by muse, mutect2, varscan2
- PLXNA4 | c.822G>A p.Q274= | Silent (SNP) | VAF 36/230 reads (16%) | called by muse, mutect2, varscan2
- PM20D1 | c.657G>A p.G219= | Silent (SNP) | VAF 17/133 reads (13%) | called by muse, mutect2, varscan2
- POLQ | c.2739T>C p.H913= | Silent (SNP) | VAF 39/154 reads (25%) | catalogued as rs759356478; called by muse, mutect2, varscan2
- PPP1R10 | c.1635A>T p.S545= | Silent (SNP) | VAF 61/253 reads (24%) | called by muse, mutect2, varscan2
- PRODH2 | c.714G>T p.T238= (on ENST00000301175; = p.T162= on NM_021232.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 38/149 reads (26%) | called by muse, mutect2, varscan2
- RACGAP1 | c.1300C>T p.L434= | Silent (SNP) | VAF 12/389 reads (3%) | called by muse, mutect2
- RANBP10 | c.1494G>T p.R498= | Silent (SNP) | VAF 73/225 reads (32%) | called by muse, mutect2, varscan2
- RBP3 | c.1993C>A p.R665= | Silent (SNP) | VAF 39/288 reads (14%) | catalogued as rs782074671; called by muse, mutect2, varscan2
- RBPJ | c.78G>A p.G26= | Silent (SNP) | VAF 32/343 reads (9%) | called by muse, mutect2
- RFPL4AL1 | c.345G>A p.L115= | Silent (SNP) | VAF 115/1113 reads (10%) | called by muse, mutect2, varscan2
- RLN3 | c.75C>A p.A25= | Silent (SNP) | VAF 48/203 reads (24%) | called by muse, mutect2, varscan2
- RNF150 | c.168G>T p.G56= | Silent (SNP) | VAF 67/232 reads (29%) | called by muse, mutect2, varscan2
- RTN1 | c.1485G>T p.L495= | Silent (SNP) | VAF 11/55 reads (20%) | called by muse, mutect2, varscan2
- RYR3 | c.4557C>T p.H1519= | Silent (SNP) | VAF 55/164 reads (34%) | catalogued as rs757477191, COSV66781750; called by muse, mutect2, varscan2
- S1PR5 | c.807G>A p.L269= | Silent (SNP) | VAF 103/347 reads (30%) | called by muse, mutect2, varscan2
- SDR16C5 | c.222G>A p.K74= | Silent (SNP) | VAF 104/603 reads (17%) | called by muse, mutect2, varscan2
- SH2D5 | c.156G>T p.L52= | Silent (SNP) | VAF 33/300 reads (11%) | called by muse, mutect2, varscan2
- SLC16A9 | c.324C>A p.S108= | Silent (SNP) | VAF 52/209 reads (25%) | called by muse, mutect2, varscan2
- SNAI1 | c.30C>A p.P10= | Silent (SNP) | VAF 94/469 reads (20%) | called by muse, mutect2, varscan2
- SPATA31D1 | c.2487C>A p.A829= | Silent (SNP) | VAF 128/529 reads (24%) | called by muse, mutect2, varscan2
- SREBF2 | c.312G>T p.A104= | Silent (SNP) | VAF 182/754 reads (24%) | called by muse, varscan2
- ST6GAL2 | c.210G>A p.P70= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as rs1363743593, COSV64526171, COSV64531672; called by muse, mutect2, varscan2
- STK31 | c.1989A>G p.Q663= | Silent (SNP) | VAF 36/228 reads (16%) | called by muse, mutect2, varscan2
- STYXL2 | c.2466C>T p.P822= | Silent (SNP) | VAF 46/254 reads (18%) | catalogued as COSV54808211; called by muse, mutect2, varscan2
- SYNDIG1 | c.534G>A p.P178= | Silent (SNP) | VAF 66/335 reads (20%) | catalogued as rs536225349, COSV100965456, COSV65233168; called by muse, mutect2, varscan2
- TARM1 | c.756G>T p.V252= (on ENST00000616041 / NM_001330650.1; = p.V244= on NM_001135686.3) | Silent (SNP) | VAF 61/354 reads (17%) | called by muse, varscan2
- TCTEX1D4 | c.297G>A p.A99= | Silent (SNP) | VAF 148/314 reads (47%) | catalogued as rs775517156; called by muse, mutect2, varscan2
- TET1 | c.6276A>T p.P2092= | Silent (SNP) | VAF 46/440 reads (10%) | called by muse, mutect2
- TEX47 | c.258A>T p.T86= | Silent (SNP) | VAF 74/337 reads (22%) | called by muse, mutect2, varscan2
- TMCO3 | c.84G>T p.V28= | Silent (SNP) | VAF 14/60 reads (23%) | called by muse, mutect2, varscan2
- TNR | c.636G>T p.G212= | Silent (SNP) | VAF 66/322 reads (20%) | catalogued as rs750486420; called by muse, mutect2, varscan2
- TNR | c.66G>T p.L22= | Silent (SNP) | VAF 79/324 reads (24%) | catalogued as COSV54887992, COSV99687468; called by muse, mutect2, varscan2
- TRPC5 | c.2769C>A p.S923= | Silent (SNP) | VAF 26/151 reads (17%) | called by muse, mutect2, varscan2
- TSC2 | c.3627G>A p.L1209= | Silent (SNP) | VAF 164/611 reads (27%) | called by muse, mutect2, varscan2
- TUBGCP4 | c.256C>T p.L86= | Silent (SNP) | VAF 197/581 reads (34%) | catalogued as rs1265468741; called by muse, mutect2, varscan2
- UNC80 | c.3073C>A p.R1025= | Silent (SNP) | VAF 34/282 reads (12%) | catalogued as COSV55893285; called by mutect2, varscan2
- VIL1 | c.861C>A p.I287= | Silent (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2, varscan2
- VNN1 | c.117C>T p.A39= | Silent (SNP) | VAF 93/598 reads (16%) | called by muse, mutect2, varscan2
- VRTN | c.1965C>A p.A655= | Silent (SNP) | VAF 27/256 reads (11%) | called by muse, mutect2, varscan2
- WDR97 | c.4734G>T p.P1578= | Silent (SNP) | VAF 30/122 reads (25%) | catalogued as rs1313920363; called by muse, mutect2, varscan2
- WNK1 | c.3162A>G p.A1054= (on ENST00000315939 / NM_018979.4; = p.A807= on NM_014823.3) | Silent (SNP) | VAF 207/949 reads (22%) | called by muse, mutect2, varscan2
- ZBED6 | c.2821C>T p.L941= | Silent (SNP) | VAF 32/190 reads (17%) | catalogued as rs1032776484; called by muse, mutect2, varscan2
- ZNF341 | c.1584G>A p.L528= (on ENST00000375200 / NM_001282935.1; = p.L521= on NM_032819.4) | Silent (SNP) | VAF 87/336 reads (26%) | called by muse, mutect2, varscan2
- ZNF423 | c.519G>T p.P173= (on ENST00000563137 / NM_001379286.1; = p.P165= on NM_015069.4) | Silent (SNP) | VAF 63/201 reads (31%) | called by muse, mutect2, varscan2
- ZNF573 | c.1611C>T p.F537= (on ENST00000536220 / NM_001172692.1; = p.F479= on NM_152360.3) | Silent (SNP) | VAF 19/167 reads (11%) | called by muse, mutect2, varscan2
- ZNF813 | c.1026T>C p.L342= | Silent (SNP) | VAF 119/621 reads (19%) | called by muse, mutect2, varscan2
- ZNF831 | c.1284G>T p.R428= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as COSV64040337; called by muse, mutect2, varscan2
- AAAS | c.1331+15G>T | Intron (SNP) | VAF 224/694 reads (32%) | called by muse, mutect2, varscan2
- AC007557.3 | n.2629C>G | RNA (SNP) | VAF 76/293 reads (26%) | called by muse, mutect2, varscan2
- AC021066.2 | n.373G>T | RNA (SNP) | VAF 92/334 reads (28%) | called by muse, mutect2, varscan2
- AC022031.2 | n.156+67555A>G | Intron (SNP) | VAF 40/285 reads (14%) | called by muse, mutect2, varscan2
- AC097636.1 | c.-36A>G | 5'UTR (SNP) | VAF 61/214 reads (29%) | called by muse, mutect2, varscan2
- AC136759.1 | n.590G>C | RNA (SNP) | VAF 55/526 reads (10%) | called by muse, mutect2, varscan2
- AC235097.1 | n.404G>C | RNA (SNP) | VAF 36/154 reads (23%) | catalogued as rs889871898; called by muse, mutect2
- AFMID | c.154+1581C>G | Intron (SNP) | VAF 34/96 reads (35%) | called by muse, mutect2, varscan2
- AKT2 | c.639+109G>T | Intron (SNP) | VAF 100/531 reads (19%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73845699 C>A | 5'Flank (SNP) | VAF 35/366 reads (10%) | called by muse, mutect2, varscan2
- ALG2 | c.*596A>G | 3'UTR (SNP) | VAF 24/204 reads (12%) | called by muse, mutect2, varscan2
- ALG2 | c.-18A>T | 5'UTR (SNP) | VAF 18/67 reads (27%) | called by muse, mutect2, varscan2
- ARHGEF25 | chr12:57610650 C>T | 5'Flank (SNP) | VAF 10/110 reads (9%) | catalogued as rs1292544426, COSV54087041; called by muse, mutect2
- ARHGEF4 | chr2:130916447 G>T | 5'Flank (SNP) | VAF 30/144 reads (21%) | called by muse, mutect2, varscan2
- ARMC4 | c.3021+7304G>C | Intron (SNP) | VAF 46/157 reads (29%) | called by muse, mutect2, varscan2
- ATP10A | c.449+353C>A | Intron (SNP) | VAF 81/334 reads (24%) | called by muse, mutect2, varscan2
- CD5L | c.-1C>A | 5'UTR (SNP) | VAF 53/266 reads (20%) | called by muse, mutect2, varscan2
- CDKN2A | chr9:21974863 C>A | 5'Flank (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2
- CHRNA4 | c.*2180G>T | 3'UTR (SNP) | VAF 70/220 reads (32%) | catalogued as rs909467149; called by muse, mutect2, varscan2
- CLU | c.*526C>A | 3'UTR (SNP) | VAF 88/321 reads (27%) | called by muse, mutect2, varscan2
- CTNNA2 | c.1057-64868G>T | Intron (SNP) | VAF 22/232 reads (9%) | called by muse, mutect2
- CYP2B7P | n.1149G>T | RNA (SNP) | VAF 42/204 reads (21%) | called by muse, mutect2, varscan2
- DIP2C | c.85+38263A>T | Intron (SNP) | VAF 149/710 reads (21%) | called by muse, mutect2, varscan2
- DIS3L2 | c.702+11A>G | Intron (SNP) | VAF 24/179 reads (13%) | catalogued as rs752191280; called by muse, mutect2, varscan2
- DNM2 | c.1336-45G>T | Intron (SNP) | VAF 43/138 reads (31%) | called by muse, mutect2, varscan2
- DST | c.4297-996A>T | Intron (SNP) | VAF 82/490 reads (17%) | called by muse, mutect2, varscan2
- EIF5AL1 | chr10:79510564 C>T | 5'Flank (SNP) | VAF 46/522 reads (9%) | called by muse, mutect2
- ELAPOR2 | c.2169+427C>G | Intron (SNP) | VAF 108/614 reads (18%) | called by muse, mutect2, varscan2
- ELK1 | chrX:47650600 C>A | 5'Flank (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- EMD | c.-11C>A | 5'UTR (SNP) | VAF 81/428 reads (19%) | called by muse, mutect2, varscan2
- FAM122C | c.345+2496A>G | Intron (SNP) | VAF 86/439 reads (20%) | called by muse, mutect2, varscan2
- FER1L4 | n.3394C>T | RNA (SNP) | VAF 64/198 reads (32%) | called by muse, mutect2, varscan2
- FLNA | c.7023+49G>T | Intron (SNP) | VAF 31/154 reads (20%) | called by muse, mutect2, varscan2
- FRMPD2 | c.-11del | 5'UTR (DEL) | VAF 34/205 reads (17%) | called by mutect2, pindel, varscan2
- GABRG2 | c.1248+325G>T | Intron (SNP) | VAF 41/178 reads (23%) | called by muse, mutect2, varscan2
- GALT | c.1059+40A>G | Intron (SNP) | VAF 46/200 reads (23%) | called by muse, mutect2, varscan2
- GOLGA8J | c.591+81A>G | Intron (SNP) | VAF 101/710 reads (14%) | called by muse, mutect2, varscan2
- GPC3 | c.*35C>G | 3'UTR (SNP) | VAF 100/428 reads (23%) | called by muse, mutect2, varscan2
- GPHN | c.864+20385G>T | Intron (SNP) | VAF 28/322 reads (9%) | called by muse, mutect2
- GPR89B | c.728-575G>T | Intron (SNP) | VAF 26/322 reads (8%) | called by muse, mutect2, varscan2
- H3P12 | chr3:109410187 C>A | 5'Flank (SNP) | VAF 194/626 reads (31%) | called by muse, mutect2, varscan2
- HLA-F | chr6:29727976 C>T | 3'Flank (SNP) | VAF 39/161 reads (24%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-1915G>T | Intron (SNP) | VAF 52/367 reads (14%) | called by muse, varscan2
- KIF28P | n.2542dup | RNA (INS) | VAF 68/378 reads (18%) | called by mutect2, pindel, varscan2
- LHX1 | chr17:36937235 G>T | 5'Flank (SNP) | VAF 47/172 reads (27%) | called by muse, mutect2, varscan2
- LINC02740 | n.344G>T | RNA (SNP) | VAF 26/280 reads (9%) | called by muse, mutect2
- MIR411 | n.59A>G | RNA (SNP) | VAF 19/173 reads (11%) | called by muse, mutect2, varscan2
- MMP26 | c.-145+92595C>A | Intron (SNP) | VAF 39/318 reads (12%) | called by muse, mutect2, varscan2
- NDUFV3 | c.-6A>T | 5'UTR (SNP) | VAF 24/422 reads (6%) | called by muse, mutect2
- NLRP12 | c.*32C>A | 3'UTR (SNP) | VAF 28/600 reads (5%) | called by muse, mutect2
- NLRP12 | c.2244-202C>A | Intron (SNP) | VAF 30/123 reads (24%) | called by muse, mutect2, varscan2
- NMNAT2 | c.574+11C>A | Intron (SNP) | VAF 92/363 reads (25%) | called by muse, mutect2, varscan2
- NOL9 | chr1:6519449 T>A | 3'Flank (SNP) | VAF 102/562 reads (18%) | called by muse, varscan2
- NOL9 | chr1:6519450 C>A | 3'Flank (SNP) | VAF 102/566 reads (18%) | catalogued as rs754291719; called by muse, varscan2
- NPIPB1P | n.842A>G | RNA (SNP) | VAF 80/522 reads (15%) | catalogued as rs760590854; called by mutect2, varscan2
- OBSCN | c.11660-2638G>A | Intron (SNP) | VAF 24/359 reads (7%) | called by muse, mutect2
- PAK3 | c.277-1638A>G | Intron (SNP) | VAF 21/158 reads (13%) | called by muse, mutect2, varscan2
- PEG10 | c.*1128C>T | 3'UTR (SNP) | VAF 50/138 reads (36%) | called by muse, mutect2, varscan2
- PSG11 | c.*13C>A | 3'UTR (SNP) | VAF 54/276 reads (20%) | called by muse, mutect2, varscan2
- PTGFR | c.798+4395C>T | Intron (SNP) | VAF 22/101 reads (22%) | catalogued as rs1488611371; called by muse, mutect2, varscan2
- RN7SL319P | chr15:75780994 C>T | 5'Flank (SNP) | VAF 82/801 reads (10%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34158607 G>T | 5'Flank (SNP) | VAF 20/67 reads (30%) | called by muse, mutect2, varscan2
- RNU6-1191P | chr16:81108569 T>C | 5'Flank (SNP) | VAF 58/166 reads (35%) | called by muse, mutect2, varscan2
- SIRT7 | c.-9A>G | 5'UTR (SNP) | VAF 103/275 reads (37%) | catalogued as rs775606610; called by muse, mutect2, varscan2
- SPANXN1 | c.-63A>T | 5'UTR (SNP) | VAF 63/332 reads (19%) | called by muse, mutect2, varscan2
- SSPOP | n.1841A>G | RNA (SNP) | VAF 23/235 reads (10%) | called by muse, mutect2, varscan2
- SYCE1 | chr10:133568060 G>T | 5'Flank (SNP) | VAF 11/37 reads (30%) | catalogued as rs781453249; called by muse, mutect2, varscan2
- SYTL2 | c.1459+1626G>C | Intron (SNP) | VAF 35/204 reads (17%) | called by muse, mutect2, varscan2
- TAF1D | c.-144G>T | 5'UTR (SNP) | VAF 45/317 reads (14%) | called by muse, mutect2, varscan2
- TBXT | c.*46G>A | 3'UTR (SNP) | VAF 50/189 reads (26%) | catalogued as rs762853565; called by muse, mutect2, varscan2
- TCP11X2 | chrX:102460504 C>A | 3'Flank (SNP) | VAF 8/44 reads (18%) | called by mutect2, varscan2
- TIMM8A | c.132+38A>G | Intron (SNP) | VAF 43/305 reads (14%) | called by muse, mutect2, varscan2
- TNFRSF4 | c.763+37G>T | Intron (SNP) | VAF 12/89 reads (13%) | called by muse, mutect2, varscan2
- TTBK1 | c.1986+6491C>A | Intron (SNP) | VAF 126/299 reads (42%) | called by muse, mutect2, varscan2
- TTC37 | c.2515+11A>T | Intron (SNP) | VAF 128/520 reads (25%) | called by muse, mutect2, varscan2
- TUBB8P7 | n.906del | RNA (DEL) | VAF 170/1269 reads (13%) | called by pindel, varscan2
- UBE2A | c.125+40C>T | Intron (SNP) | VAF 74/317 reads (23%) | catalogued as rs924759650; called by muse, mutect2, varscan2
- ZBTB16 | c.*19G>C | 3'UTR (SNP) | VAF 51/350 reads (15%) | called by muse, mutect2, varscan2
- ZNF557 | c.-14G>T | 5'UTR (SNP) | VAF 60/304 reads (20%) | called by muse, mutect2, varscan2
